Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A7D0, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A7D0-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: F
ADM DATE:

PAT TYPE:

OPER DATE:

PROCEDURE: SPHS

year-old female with pheochromocytoma. Operative Procedure: Left posterior approach. Retroperitoneal adrenalectomy. Fresh.

PROCEDURE: SPGD

1. "Left adrenal gland." Received is a 60 gram adrenal specimen (8.0 x 4.5 x 4.0 cm). Previously inked blue. Cross sectioning reveals a 4.5 x 4.0 x 3.0 cm encapsulated mass within the adrenal gland. The mass is partially solid and cystic with hemorrhagic and necrotic areas.

- 1A. Section of solid area of mass.
- 1B. Section of hemorrhagic/necrotic area.
- 1C. Section of hemorrhagic area.
- 1D. Section of solid area.
- 1E. Section of mass and normal adrenal gland.
- 1F. Section of normal adrenal gland.
- (1 each)

*ICD-O-3
Pheochromocytoma NOS 8720/0
Site @ Adrenal gland @ 74.9
JW 1/21/14*

PROCEDURE: SPDY

1. Left adrenal gland, excision: Pheochromocytoma (4.5 cm). Margins negative.

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

H-PA Discrepancy		X

Source: NCI Genomic Data Commons file c16ea461-6af9-46bd-94b6-690644cf6654 (TCGA-RW-A7D0.E3FD9EF7-2F86-47D6-90ED-B912F333C419.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).